Somatic mutation profile of tumor specimen TCGA-AA-A02H-01A (aliquot TCGA-AA-A02H-01A-01W-A00E-09) from TCGA case TCGA-AA-A02H, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IV; Age at diagnosis: 74.9 years (27,362 days).
Specimen TCGA-AA-A02H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a44a6b34-36ff-4c46-aaab-1eb527a2e861.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-A02H-10A (Blood Derived Normal), aliquot TCGA-AA-A02H-10A-01W-A00E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bb754d30-cbc6-4c0b-8061-e90127ba154b

The open-access MAF lists 79 somatic variants for this specimen: 62 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 16, Frame Shift Del 5, Splice Site 2, Nonsense Mutation 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NBN | c.994+1G>T p.X332_splice | Splice Site (SNP) | VAF 147/280 reads (53%) | catalogued as rs1554562083; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.338T>G p.F113C | Missense Mutation (SNP) | VAF 52/76 reads (68%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1567555667, COSV52680942, COSV52985275; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADNP | c.2453A>G p.Y818C | Missense Mutation (SNP) | VAF 209/289 reads (72%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV62424605; called by muse, mutect2, varscan2
- AHNAK | c.1302G>T p.M434I | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.059); catalogued as COSV57205564, COSV57212149; called by muse, mutect2, varscan2
- AMZ1 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as COSV56685131; called by muse, mutect2, varscan2
- ANK2 | c.533C>A p.A178E | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52148836, COSV52150935; called by muse, mutect2, varscan2
- APC | c.919del p.H307Ifs*29 | Frame Shift Del (DEL) | VAF 65/119 reads (55%) | catalogued as COSV57328435; called by mutect2, pindel, varscan2
- AREG | c.230C>T p.S77L | Missense Mutation (SNP) | VAF 112/209 reads (54%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as rs769439500; called by muse, mutect2, varscan2
- ARHGAP15 | c.1133C>T p.A378V | Missense Mutation (SNP) | VAF 91/117 reads (78%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs749157476, COSV54480561; called by muse, mutect2, varscan2
- ASTN1 | c.1807G>A p.D603N | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs775782427, COSV56062768; called by muse, mutect2, varscan2
- BRPF3 | c.2492A>G p.K831R | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV60206288; called by muse, mutect2, varscan2
- C9 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 81/435 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371134723; called by muse, mutect2, varscan2
- CACNA2D1 | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 197/482 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as rs1340629145, COSV62374142; called by muse, mutect2, varscan2
- CAMK2D | c.289G>C p.E97Q | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV56426783; called by muse, mutect2, varscan2
- CDH23 | c.7087G>A p.E2363K | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753690054, COSV56450872; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDK14 | c.748C>T p.R250C (on ENST00000380050 / NM_001287135.2; = p.R232C on NM_012395.3) | Missense Mutation (SNP) | VAF 154/377 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.641); catalogued as rs758302947, COSV56025686; called by muse, mutect2, varscan2
- CENPC | c.2353G>T p.E785* | Nonsense Mutation (SNP) | VAF 13/36 reads (36%) | catalogued as COSV56621478; called by muse, mutect2, varscan2
- CEP126 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs78220060, COSV54822239; called by muse, mutect2, varscan2
- CNTN4 | c.2468C>T p.A823V | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.039); catalogued as rs748582277, COSV61868864; called by muse, mutect2, varscan2
- COL16A1 | c.1793A>G p.K598R | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as COSV54701600; called by muse, mutect2, varscan2
- CRYGC | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 98/129 reads (76%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as rs1209233008, COSV56408662; called by muse, mutect2, varscan2
- DNAH17 | c.10969A>G p.R3657G | Missense Mutation (SNP) | VAF 19/24 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67750422; called by muse, varscan2
- ELMO1 | c.550-1G>A p.X184_splice | Splice Site (SNP) | VAF 84/183 reads (46%) | catalogued as COSV60310798; called by muse, mutect2, varscan2
- GRIA1 | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 76/101 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs146865938; called by muse, mutect2, varscan2
- H1-3 | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs759916366, COSV55096983; called by muse, mutect2, varscan2
- HAPLN1 | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.381); catalogued as rs753012193, COSV57151856; called by muse, mutect2, varscan2
- HS6ST3 | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.103); catalogued as COSV65009491; called by muse, mutect2
- KLHL24 | c.698T>A p.V233D | Missense Mutation (SNP) | VAF 109/194 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54424863; called by muse, mutect2, varscan2
- LATS1 | c.2969G>A p.R990Q | Missense Mutation (SNP) | VAF 107/149 reads (72%) | SIFT tolerated (0.12); PolyPhen benign (0.433); catalogued as rs1253121553, COSV53586962; called by muse, mutect2, varscan2
- LRP1B | c.10137G>T p.E3379D | Missense Mutation (SNP) | VAF 263/337 reads (78%) | SIFT tolerated (0.96); PolyPhen benign (0.04); catalogued as COSV67192449; called by muse, mutect2, varscan2
- LRRIQ1 | c.3134A>T p.N1045I | Missense Mutation (SNP) | VAF 52/253 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67826775; called by muse, mutect2, varscan2
- MAGEA12 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT tolerated (0.22); PolyPhen benign (0.313); catalogued as rs1434715732, COSV63294268; called by muse, mutect2, varscan2
- MAGEB2 | c.394G>A p.V132I | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs758812052, COSV100975663, COSV66780301; called by muse, mutect2, varscan2
- MFSD8 | c.1205C>T p.S402L | Missense Mutation (SNP) | VAF 44/81 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs200745039; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NPTN | c.527C>A p.S176Y | Missense Mutation (SNP) | VAF 20/229 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.186); catalogued as COSV54739834; called by muse, mutect2
- OR4S1 | c.890G>T p.R297M | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); catalogued as COSV60678790; called by muse, mutect2, varscan2
- OR5A2 | c.955A>G p.I319V | Missense Mutation (SNP) | VAF 119/227 reads (52%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs556816690, COSV57390498; called by muse, mutect2, varscan2
- PCDH1 | c.1327C>T p.R443C | Missense Mutation (SNP) | VAF 11/195 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1441383396; called by muse, mutect2
- PGK2 | c.314A>T p.E105V | Missense Mutation (SNP) | VAF 133/270 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.432); catalogued as rs776820903, COSV59163035; called by muse, mutect2, varscan2
- PTPN13 | c.2810G>T p.C937F | Missense Mutation (SNP) | VAF 55/261 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.235); catalogued as COSV57403414; called by muse, mutect2, varscan2
- RNF175 | c.340G>A p.V114I | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs370409419; called by muse, mutect2
- SAMD9 | c.2764G>A p.A922T | Missense Mutation (SNP) | VAF 92/214 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs369626579, COSV104429960, COSV66073362; called by muse, mutect2, varscan2
- SCARA5 | c.1234C>T p.R412W | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1465178712, COSV61571139; called by muse, mutect2, varscan2
- SLC22A8 | c.1096G>A p.D366N | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1362681258, COSV60323992; called by muse, mutect2, varscan2
- SLCO1A2 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 143/192 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs11568564, CM068630; called by muse, mutect2, varscan2
- SNX2 | c.1465G>A p.V489I | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs760493667, COSV65347774; called by muse, mutect2, varscan2
- SPRR2E | c.16C>A p.Q6K | Missense Mutation (SNP) | VAF 61/326 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV64203603; called by muse, varscan2
- TTN | c.62473T>G p.S20825A (on ENST00000591111; = p.S13401A on NM_003319.4) | Missense Mutation (SNP) | VAF 63/214 reads (29%) | PolyPhen benign (0.415); catalogued as COSV59914399; called by muse, mutect2, varscan2
- TYW1 | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.006); catalogued as COSV55887146; called by muse, mutect2, varscan2
- USH2A | c.6808G>T p.V2270F | Missense Mutation (SNP) | VAF 84/169 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.916); catalogued as COSV56334902; called by muse, mutect2, varscan2
- WIF1 | c.215A>T p.K72I | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.471); catalogued as COSV54130051, COSV54130847; called by muse, mutect2, varscan2
- ZFHX4 | c.9037G>A p.G3013R | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as rs1360488245, COSV50493419, COSV99254152; called by muse, mutect2, varscan2
- AGAP1 | c.1681del p.L561Sfs*43 (on ENST00000304032 / NM_001037131.3; = p.L508Sfs*43 on NM_014914.5) | Frame Shift Del (DEL) | VAF 45/156 reads (29%) | called by mutect2, pindel, varscan2
- BMP4 | c.330_341del p.A111_A114del | In Frame Del (DEL) | VAF 22/27 reads (81%) | called by mutect2, pindel, varscan2
- HMCN1 | c.993C>A p.F331L | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.985); called by muse, mutect2
- MAK16 | c.733G>T p.D245Y | Missense Mutation (SNP) | VAF 7/175 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); called by muse, mutect2
- MDN1 | c.16411G>T p.A5471S | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- MTUS2 | c.2179C>G p.Q727E | Missense Mutation (SNP) | VAF 770/885 reads (87%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- N4BP1 | c.2157_2166del p.I719Mfs*8 | Frame Shift Del (DEL) | VAF 21/139 reads (15%) | called by mutect2, pindel, varscan2
- SERPIND1 | c.380del p.N127Tfs*15 | Frame Shift Del (DEL) | VAF 23/57 reads (40%) | called by mutect2, pindel, varscan2
- SPATA31A1 | c.822C>A p.N274K | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ZNF565 | c.954del p.Y319Tfs*44 (on ENST00000355114; = p.Y279Tfs*44 on NM_152477.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 27/196 reads (14%) | called by mutect2, pindel, varscan2
- ABCA13 | c.12825C>T p.G4275= | Silent (SNP) | VAF 91/216 reads (42%) | catalogued as rs762367233, COSV68944007, COSV68951470; called by muse, mutect2, varscan2
- CSMD3 | c.4074C>T p.G1358= (on ENST00000297405 / NM_001363185.1; = p.G1254= on NM_052900.3) | Silent (SNP) | VAF 27/155 reads (17%) | catalogued as COSV52115778, COSV52243213; called by muse, mutect2, varscan2
- EGFLAM | c.2010C>T p.H670= | Silent (SNP) | VAF 55/122 reads (45%) | catalogued as rs199798525, COSV59292831; called by muse, mutect2, varscan2
- FAM120C | c.786C>T p.S262= | Silent (SNP) | VAF 40/216 reads (19%) | catalogued as rs1388220058, COSV60257804; called by muse, mutect2, varscan2
- GFPT2 | c.1248C>T p.D416= | Silent (SNP) | VAF 17/20 reads (85%) | catalogued as rs747012267, COSV53806728; called by muse, mutect2, varscan2
- GRIN3A | c.693G>A p.E231= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV100701367, COSV62451415; called by muse, mutect2
- GYPB | c.57A>C p.A19= | Silent (SNP) | VAF 131/242 reads (54%) | catalogued as COSV51621073; called by muse, mutect2, varscan2
- KLRF1 | c.369G>A p.G123= | Silent (SNP) | VAF 51/321 reads (16%) | catalogued as rs765136114; called by muse, mutect2, varscan2
- KRT76 | c.912G>T p.L304= | Silent (SNP) | VAF 37/68 reads (54%) | catalogued as COSV60119397; called by muse, mutect2, varscan2
- L3MBTL1 | c.1374C>T p.T458= (on ENST00000418998 / NM_001377303.1; = p.T368= on NM_015478.7) | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as rs576853992, COSV64227987; called by muse, mutect2, varscan2
- LCP2 | c.441G>A p.P147= | Silent (SNP) | VAF 11/15 reads (73%) | catalogued as rs369364060; called by muse, mutect2, varscan2
- OR8H2 | c.522T>C p.I174= | Silent (SNP) | VAF 171/779 reads (22%) | catalogued as COSV57943458; called by muse, mutect2, varscan2
- PAX3 | c.1230C>T p.Y410= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as rs147111779; called by muse, mutect2, varscan2
- PLXNA4 | c.4230C>T p.A1410= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs749584774, COSV58108649; called by muse, mutect2, varscan2
- YY2 | c.405G>A p.Q135= | Silent (SNP) | VAF 26/57 reads (46%) | catalogued as COSV63410875; called by muse, mutect2, varscan2
- ZNF573 | c.1752T>C p.C584= (on ENST00000536220 / NM_001172692.1; = p.C526= on NM_152360.3) | Silent (SNP) | VAF 125/486 reads (26%) | catalogued as COSV59823663; called by muse, mutect2, varscan2
- DENND10P1 | n.368C>A | RNA (SNP) | VAF 70/350 reads (20%) | catalogued as rs1315254552; called by muse, mutect2, varscan2
